Surgical pathology report (de-identified scan), TCGA case TCGA-GJ-A9DB, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-GJ-A9DB-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0
p 3/3/14

Operative Procedure:
Right hepatectomy, cholecystectomy

Specimen Received:
A: Gallbladder
B: Portal lymph node
C: Right hepatectomy (FS)
D: Liver right lobe

Final Pathologic Diagnosis:
A. Gallbladder, cholecystectomy:
No significant pathologic change.
B. Lymph node, portal, resection:
Four benign lymph nodes negative for malignancy (0/4).
C. Liver, right hepatectomy:
Hepatocellular carcinoma, moderately differentiated.

Specimen: Liver, gallbladder
Procedure: Partial hepatectomy
Tumor histologic type: Hepatocellular carcinoma
Tumor size: 6.0 cm (greatest dimension)
Tumor focality: Unifocal
Number of tumors: One
Histologic type: Hepatocellular carcinoma
Histologic grade: Moderately differentiated
Tumor extension: Tumor confined to liver

Margins:
Parenchymal: Uninvolved (1.7 cm away)
Frozen section diagnosis confirmed.

Lymph-vascular invasion:
Macroscopic venous (large vessel) invasion: Not identified
Microscopic (small vessel) invasion: Not identified

Pathologic staging:
TNM descriptors: None known
Primary tumor: pT1
Regional lymph nodes: pN0
Number examined: 4
Number involved: 0
Distant metastasis: Not known

Additional pathologic findings: Steatosis with

[page 2 of 3]
perisinusoidal, periportal and focal bridging fibrosis (stage 2-3/ 4) (trichrome stain).

D. Liver, right lobe, excision:

Steatosis with perisinusoidal, periportal and focal bridging fibrosis (stage 2-3/ 4)

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSC: Right hepatectomy (gross only):

Tumor 17 mm from margin.

Specimen received:

Specimen reported:

Gross Description:

Received are four formalin filled containers labeled with the patient's last name, and surgical case number

The container A is additionally labeled, "Part A gallbladder." The specimen consists of a gallbladder measuring 9 x 3.5 x 3.5 cm. The serosa is green-blue-purple, smooth and glistening. There are no lymph nodes in the fat adjacent to cystic duct. The lumen contains a moderate amount of yellow-green bile and there is no choleliths identified. The mucosa is yellow-green and velvety. The wall thickness is 0.3 cm. The cystic duct is patent without any impact. The diameter of cystic duct is 0.2 cm. Representative sections are submitted in cassette A1.

Part B is additionally labeled, "portal lymph nodes." The specimen consists of fibroadipose tissue measuring 2 x 1.5 x 0.5 cm. Upon sectioning, multiple lymph nodes are identified and the specimen is submitted entirely in cassette B1 and B2.

Part C is additionally labeled, "right hepatectomy (gross only)." The specimen consists of a right lobe of liver. It has previously been surgically dissected already. The specimen measures 21 x 11 x 11 cm and weighs 1400 g. The capsule is green-brown without nodularity. A lobulated yellow-white mass has been found in the parenchyma. It measures 6 x 5 x 4 cm and is 0.6 cm from the liver capsule. The mass is 1.7 cm from the surgical margin. The surgical margin has already been inked with black color. The cutting section of the mass is solid. The rest of the liver parenchyma is pink-tan, smooth without nodularities. Representative sections are submitted as follows:

C1 surgical margin with tubular structures which are consistent with blood vessels;

C2 shaved surgical margin;

C3,4 mass to surgical margin;

[page 3 of 3]
C5,6 mass to capsule;
C7 normal liver parenchyma.

Part D is additionally labeled, "liver right lobe" and the specimen consists of a fragment of liver tissues measuring 8 x 4 x 3 cm and it weighs 44 g and the new surgical margin has been inked black and the rest of parenchyma margin has been inked blue. The liver capsule has not been inked. Upon step-sectioning there is no tumor mass. The section is perpendicular to the new surgical margin and representative sections have been submitted in D1 through D6.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Surgical Pathology Report

Taken: Age:) Gender: M

Source: NCI Genomic Data Commons file 7753ee12-d5ce-4b45-bfac-8f6f4567fcd6 (TCGA-GJ-A9DB.8B2D3FA5-D673-4B70-B153-7EACE17A50E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).